Somatic mutation profile of tumor specimen TCGA-VD-A8K9-01A (aliquot TCGA-VD-A8K9-01A-11D-A39W-08) from TCGA case TCGA-VD-A8K9, project TCGA-UVM (Uveal Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Spindle cell melanoma, type B; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIA; Age at diagnosis: 72.0 years (26,292 days).
Specimen TCGA-VD-A8K9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 14905c50-52c0-4fe8-a95f-fc1f74d5baf5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VD-A8K9-10A (Blood Derived Normal), aliquot TCGA-VD-A8K9-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a1eb71d7-a10e-4be9-a795-f5d27f6eddef

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 5, Silent 4, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAQ | c.626A>C p.Q209P | Missense Mutation (SNP) | VAF 35/81 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121913492, COSV54105903, COSV54105914, COSV54108414; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SF3B1 | c.1873C>T p.R625C | Missense Mutation (SNP) | VAF 19/37 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs775623976, COSV59205859, COSV59212489, COSV59228873; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CYP1A1 | c.244C>A p.P82T | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV65697158; called by muse, mutect2, varscan2
- ARID1B | c.1853C>A p.P618Q | Missense Mutation (SNP) | VAF 9/9 reads (100%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FUT10 | c.1428_*1del | Nonstop Mutation (DEL) | VAF 17/42 reads (40%) | called by mutect2, pindel, varscan2
- WDR90 | c.2891C>G p.P964R | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- LCE4A | c.297C>T p.C99= | Silent (SNP) | VAF 24/37 reads (65%) | called by muse, mutect2, varscan2
- LRRN3 | c.858A>G p.L286= | Silent (SNP) | VAF 24/53 reads (45%) | called by muse, mutect2, varscan2
- PPP2R1B | c.159A>G p.A53= | Silent (SNP) | VAF 58/117 reads (50%) | called by muse, mutect2, varscan2
- WTIP | c.1168C>T p.L390= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs370782319; called by muse, mutect2, varscan2
